Somatic mutation profile of tumor specimen TCGA-61-2101-01A (aliquot TCGA-61-2101-01A-01W-0722-08) from TCGA case TCGA-61-2101, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G2; Age at diagnosis: 55.5 years (20,287 days).
Specimen TCGA-61-2101-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b76eede5-4498-4710-9f0c-b282577e91c6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-61-2101-11A (Solid Tissue Normal), aliquot TCGA-61-2101-11A-01W-0723-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8d453a8c-dd7d-48ad-9ade-f28ea445f607

The open-access MAF lists 52 somatic variants for this specimen: 37 protein-altering or splice-affecting, 14 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 14, Nonsense Mutation 3, Frame Shift Del 1, Splice Region 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EPRS1 | c.1015C>T p.R339* | Nonsense Mutation (SNP) | VAF 27/586 reads (5%) | catalogued as rs763737931, COSV65099953; ClinVar: pathogenic; called by muse, mutect2
- AMER3 | c.2552C>T p.A851V | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.034); catalogued as rs1485781166, COSV58468597; called by muse, varscan2
- ANKRD6 | c.547C>T p.R183C | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369598670; called by muse, mutect2, varscan2
- ARID1B | c.6281G>A p.R2094H | Missense Mutation (SNP) | VAF 33/376 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781613431, COSV51649575; called by muse, mutect2
- ARNT2 | c.626G>A p.R209Q | Missense Mutation (SNP) | VAF 70/201 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs772270443, COSV100309260, COSV57588620; called by muse, mutect2, varscan2
- BAZ1B | c.2696G>A p.R899H | Missense Mutation (SNP) | VAF 94/414 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59993734; called by muse, varscan2
- CCDC85A | c.1433G>A p.R478Q | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.005); catalogued as rs757108330, COSV68154899; called by muse, mutect2, varscan2
- DDX5 | c.898A>G p.I300V | Missense Mutation (SNP) | VAF 55/219 reads (25%) | SIFT tolerated (0.7); PolyPhen benign (0.031); catalogued as COSV56750917; called by muse, mutect2, varscan2
- DGKB | c.1396C>G p.R466G | Missense Mutation (SNP) | VAF 29/215 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51785301, COSV51813088, COSV99337863; called by muse, mutect2, varscan2
- DNAH11 | c.8548T>C p.C2850R | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.038); catalogued as COSV100175981; called by muse, mutect2
- DSG3 | c.2692T>G p.C898G | Missense Mutation (SNP) | VAF 119/262 reads (45%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV57129099, COSV99934587; called by muse, mutect2, varscan2
- DTD1 | c.204G>A p.M68I | Missense Mutation (SNP) | VAF 72/483 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as COSV101079535; called by muse, mutect2, varscan2
- ETV1 | c.700C>T p.P234S | Missense Mutation (SNP) | VAF 31/158 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as COSV54149738, COSV54153610; called by muse, mutect2, varscan2
- FBXL19 | c.1801G>A p.A601T | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.394); catalogued as rs748193871, COSV57945232; called by muse, mutect2, varscan2
- FPGS | c.806G>A p.R269Q | Missense Mutation (SNP) | VAF 36/67 reads (54%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.538); catalogued as rs771301592, COSV100948752; called by muse, mutect2, varscan2
- HECTD3 | c.770A>G p.N257S | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1437957319, COSV55801750; called by muse, mutect2, varscan2
- KBTBD8 | c.899A>G p.K300R | Missense Mutation (SNP) | VAF 94/335 reads (28%) | SIFT tolerated (0.53); PolyPhen benign (0.026); catalogued as COSV55130957; called by muse, mutect2, varscan2
- MAGI3 | c.2837G>A p.G946E | Missense Mutation (SNP) | VAF 31/174 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV56842893; called by muse, mutect2, varscan2
- MC1R | c.448C>G p.L150V | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100205503; called by muse, mutect2
- MGAT5 | c.1951C>T p.Q651* | Nonsense Mutation (SNP) | VAF 8/118 reads (7%) | catalogued as COSV99923848; called by muse, mutect2
- MYBL2 | c.2005G>A p.G669R | Missense Mutation (SNP) | VAF 31/255 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779332836; called by mutect2, varscan2
- MYORG | c.1202G>A p.R401H | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.139); catalogued as rs771258817, COSV52628199; called by muse, mutect2, varscan2
- OR2L13 | c.695G>A p.G232E | Missense Mutation (SNP) | VAF 31/275 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV63559458; called by muse, mutect2, varscan2
- PARD3 | c.3840G>T p.M1280I | Missense Mutation (SNP) | VAF 10/242 reads (4%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.943); catalogued as rs1401524578, COSV100630687; called by muse, mutect2
- PI4KA | c.2122G>A p.A708T | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.729); catalogued as rs1199044678, COSV99743548; called by muse, mutect2, varscan2
- PRKDC | c.9085A>G p.K3029E | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV58061337; called by muse, varscan2
- PRKDC | c.7708C>T p.P2570S | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.973); catalogued as COSV100037686; called by muse, mutect2, varscan2
- TET3 | c.5377C>T p.R1793C | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.024); catalogued as rs568566594, COSV69645170; called by muse, mutect2, varscan2
- TMEM255B | c.908C>T p.P303L | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.387); catalogued as COSV64713248; called by muse, mutect2, varscan2
- TNPO1 | c.604G>A p.A202T | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); catalogued as COSV61523560; called by muse, mutect2, varscan2
- TRPA1 | c.980A>C p.Y327S | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.292); catalogued as COSV100082692; called by muse, varscan2
- UNC45B | c.168G>A p.T56= | Splice Region (SNP) | VAF 10/22 reads (45%) | catalogued as rs755023722, COSV52099851; called by muse, mutect2, varscan2
- ZC3H7A | c.1834A>G p.I612V | Missense Mutation (SNP) | VAF 49/226 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.175); catalogued as COSV63271159; called by muse, mutect2, varscan2
- ZNF831 | c.3946C>T p.R1316* | Nonsense Mutation (SNP) | VAF 20/91 reads (22%) | catalogued as rs1211201145, COSV64037169, COSV64038407; called by muse, mutect2, varscan2
- IQGAP3 | c.1114G>T p.D372Y | Missense Mutation (SNP) | VAF 51/836 reads (6%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.521); called by muse, mutect2
- PGM5 | c.935C>T p.S312F | Missense Mutation (SNP) | VAF 38/305 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TP53 | c.255_264del p.A86Pfs*34 | Frame Shift Del (DEL) | VAF 57/73 reads (78%) | called by mutect2, pindel, varscan2
- ABCC10 | c.3762G>A p.A1254= (on ENST00000372530 / NM_001198934.2; = p.A1226= on NM_033450.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 50/210 reads (24%) | catalogued as rs201628117, COSV55086117; called by muse, mutect2, varscan2
- CCDC186 | c.663G>A p.E221= | Silent (SNP) | VAF 9/67 reads (13%) | catalogued as rs867395915, COSV65159798; called by muse, mutect2, varscan2
- DGKD | c.2688C>T p.I896= (on ENST00000264057 / NM_152879.3; = p.I852= on NM_003648.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 40/227 reads (18%) | catalogued as rs1480812455, COSV51040736, COSV99897644; called by muse, mutect2, varscan2
- ETF1 | c.246C>A p.L82= | Silent (SNP) | VAF 102/379 reads (27%) | catalogued as COSV62127998; called by muse, mutect2, varscan2
- FLNB | c.2637G>T p.P879= | Silent (SNP) | VAF 67/265 reads (25%) | catalogued as rs149334776, COSV99911169; called by muse, varscan2
- KCTD16 | c.1188G>A p.E396= | Silent (SNP) | VAF 33/111 reads (30%) | catalogued as COSV72576804, COSV72580328; called by muse, mutect2, varscan2
- KPRP | c.558C>T p.G186= | Silent (SNP) | VAF 68/447 reads (15%) | catalogued as COSV64222777; called by muse, mutect2, varscan2
- NEU3 | c.189C>T p.L63= | Silent (SNP) | VAF 162/191 reads (85%) | catalogued as COSV53638721; called by muse, mutect2, varscan2
- OR52E4 | c.618T>C p.S206= | Silent (SNP) | VAF 148/544 reads (27%) | catalogued as COSV57625903; called by muse, mutect2, varscan2
- PCDHB16 | c.1872G>A p.V624= | Silent (SNP) | VAF 6/62 reads (10%) | catalogued as COSV53369497; called by muse, mutect2, varscan2
- SUN2 | c.1137G>T p.R379= | Silent (SNP) | VAF 21/78 reads (27%) | catalogued as COSV99325193; called by muse, mutect2, varscan2
- TBX18 | c.408G>A p.P136= | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as rs924714791, COSV63737870; called by muse, varscan2
- TPM4 | c.18G>A p.K6= | Silent (SNP) | VAF 51/325 reads (16%) | catalogued as COSV61210273; called by muse, mutect2, varscan2
- VPS18 | c.639C>T p.G213= | Silent (SNP) | VAF 20/47 reads (43%) | catalogued as COSV55031903; called by muse, mutect2, varscan2
- UBA52 | c.*2G>A | 3'UTR (SNP) | VAF 22/76 reads (29%) | catalogued as COSV101471113; called by muse, mutect2, varscan2
